Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TR, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TR-01A (Primary Tumor).

1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3
Site breast, NOS C50.9

Breast, left, modified radical mastectomy: Infiltrating ductal carcinoma, Nottingham grade II (of III), forming a mass (2.3 x 2.1 x 1.7 cm) located in the superior/central aspect of the breast [AJCC pT2]. Ductal carcinoma in situ, intermediate nuclear grade, comprises approximately 5-25% of the tumor volume. Angiolymphatic invasion is present. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. The tumor does not involve the nipple, overlying skin, or underlying chest wall. All surgical resection margins, after re-excision of the anterior/superior margin, are negative for tumor (minimum tumor free margin, 0.7 cm, anterior/superior margin). The deep margin is negative for tumor (free by 0.8 cm). Multiple (22) left mid/low axillary lymph nodes are negative for metastatic carcinoma.

Lymph nodes, left high axillary, excision: Multiple (3) left high axillary lymph nodes are negative for tumor.

Lymph node, left axillary sentinel, excision: A single left axillary sentinel lymph node is positive for metastatic adenocarcinoma with one metastasis measuring 2.5 x 2.5 x 1.3 cm [AJCC pN1]. Extranodal extension is not present. Blue dye is not identified.

Source: NCI Genomic Data Commons file aea98609-3515-4e0c-bb6f-fcb8bdad635c (TCGA-AR-A0TR.6535D911-D718-4794-9D5E-6E06553464FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).